Somatic mutation profile of tumor specimen TCGA-CV-A45O-01A (aliquot TCGA-CV-A45O-01A-21D-A24D-08) from TCGA case TCGA-CV-A45O, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Gum, NOS; Tumor grade: G2; Age at diagnosis: 57.1 years (20,868 days).
Specimen TCGA-CV-A45O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f46426a3-6317-4c2a-924a-91b716161a1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A45O-10A (Blood Derived Normal), aliquot TCGA-CV-A45O-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2a6ba3c-bb42-4aa2-996c-632eab0909d6

The open-access MAF lists 148 somatic variants for this specimen: 115 protein-altering or splice-affecting, 27 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 27, Nonsense Mutation 14, Intron 2, 3'Flank 1, Frame Shift Ins 1, Splice Site 1, 5'Flank 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- GNE | c.922C>T p.R308C (on ENST00000396594 / NM_001128227.3; = p.R277C on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as rs762106720, CM086833, CM139083, COSV64951631; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB4 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs753420538, COSV55940014; called by mutect2, varscan2
- ACVR1C | c.1173C>G p.I391M | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.818); catalogued as COSV99694953; called by muse, mutect2, varscan2
- ADAM2 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs769082387, COSV55864232; called by muse, mutect2, varscan2
- ADAMTS9 | c.837G>C p.K279N | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV55790866; called by muse, varscan2
- AGO1 | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64595188; called by muse, mutect2, varscan2
- ALPK3 | c.2456G>A p.R819Q | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs116079740; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6394C>G p.R2132G | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as rs896136309, COSV51851423, COSV99784131; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6527C>T p.A2176V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV99784135; called by muse, mutect2
- AP2A1 | c.2410C>A p.Q804K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100571238; called by muse, mutect2, varscan2
- ASCC3 | c.3184C>T p.Q1062* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100226181; called by muse, mutect2, varscan2
- BMP1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs773787666, COSV100110014; called by muse, mutect2, varscan2
- CACNG6 | c.701G>A p.G234E (on ENST00000252729 / NM_145814.1; = p.G163E on NM_031897.2) | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV99403597; called by muse, mutect2, varscan2
- CAPN13 | c.928G>C p.D310H | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99700844; called by muse, mutect2
- CASP8 | c.319C>T p.Q107* (on ENST00000432109 / NM_033355.3; = p.Q139* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as COSV51851441; called by muse, mutect2, varscan2
- CDH11 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs868248780, COSV51752373; called by muse, mutect2, varscan2
- CDR1 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.298); catalogued as COSV100983434; called by muse, mutect2, varscan2
- CNR1 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.716); catalogued as rs568621412, COSV100759316; called by muse, mutect2, varscan2
- CRNN | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 33/308 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV55120885, COSV99664307; called by muse, mutect2, varscan2
- CYP26B1 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as rs1348778460, COSV99134857; called by muse, mutect2, varscan2
- DDX58 | c.1993G>A p.G665S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.705); catalogued as COSV101153158; called by muse, mutect2, varscan2
- DIAPH2 | c.797C>G p.P266R | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100234560, COSV61286407; called by muse, mutect2, varscan2
- DNAJC6 | c.727T>C p.F243L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99675473; called by muse, mutect2
- DSP | c.3826C>T p.Q1276* | Nonsense Mutation (SNP) | VAF 13/102 reads (13%) | catalogued as COSV101131631, COSV65792140; called by muse, mutect2, varscan2
- EDRF1 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV100523132, COSV100523964; called by muse, mutect2
- EIF5A | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59748360; called by muse, mutect2
- ESRP2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs1384734992, COSV99251430; called by muse, mutect2
- FAF1 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.815); catalogued as COSV100875977; called by muse, mutect2, varscan2
- FAT1 | c.10118C>G p.S3373* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV71675300; called by muse, mutect2, varscan2
- FAT1 | c.2053G>T p.E685* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV101499577; called by muse, mutect2, varscan2
- FAT2 | c.8777C>T p.A2926V | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs377736336; called by muse, mutect2, varscan2
- FBXL14 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV59336990; called by muse, mutect2, varscan2
- FBXL7 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.207); catalogued as rs1389047293, COSV61641082, COSV61645644; called by muse, mutect2
- FES | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs751786277, COSV100183276; called by muse, mutect2, varscan2
- FMN2 | c.2575C>A p.P859T | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.103); catalogued as COSV100146784; called by muse, mutect2
- FREM1 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV101084927; called by mutect2, varscan2
- FYB1 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.087); catalogued as COSV60940176, COSV60947622; called by muse, mutect2, varscan2
- GAPDH | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.08); catalogued as COSV99975640; called by muse, mutect2
- GLRA2 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.708); catalogued as COSV99491503; called by muse, mutect2, varscan2
- GOLGA2 | c.1843C>T p.Q615* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100360250, COSV100360404; called by muse, mutect2
- GOLGB1 | c.5392G>A p.E1798K | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV100511382; called by muse, mutect2, varscan2
- GRIN3A | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.014); catalogued as COSV100701717; called by muse, mutect2
- GUCY2C | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV99664026; called by muse, mutect2
- HERC1 | c.14371C>T p.Q4791* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV101496809; called by muse, mutect2, varscan2
- HIBCH | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100676254; called by muse, mutect2, varscan2
- IL10RB | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as COSV51615484, COSV99270119; called by muse, mutect2, varscan2
- IL22 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.936); catalogued as rs1268729833, COSV100048927; called by muse, mutect2, varscan2
- INSYN2A | c.543G>A p.M181I | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.022); catalogued as rs752031911, COSV99731927; called by muse, mutect2, varscan2
- JTB | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs1318332960, COSV99665805; called by muse, mutect2, varscan2
- KIF20B | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as COSV99590569; called by muse, mutect2
- KNTC1 | c.5692G>A p.D1898N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV100338678, COSV61079572; called by muse, mutect2, varscan2
- LAMC1 | c.901G>C p.D301H | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); catalogued as COSV99280265; called by muse, mutect2, varscan2
- LIG3 | c.2867G>A p.R956K | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV99253004; called by muse, mutect2
- LMF2 | c.372C>G p.F124L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99327735; called by muse, mutect2, varscan2
- MAP3K4 | c.4034G>C p.R1345T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100815556, COSV62336357; called by muse, mutect2, varscan2
- MARCHF6 | c.1802G>A p.G601E | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV99930061; called by muse, mutect2, varscan2
- METTL3 | c.988C>T p.H330Y | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99398526; called by muse, mutect2, varscan2
- MTNR1A | c.815T>C p.I272T | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100208295; called by muse, mutect2
- MYC | c.416C>G p.S139W (on ENST00000377970; = p.S154W on NM_002467.6) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52367432, COSV52370269, COSV52372085; called by muse, mutect2
- MYOM2 | c.3801-1G>A p.X1267_splice | Splice Site (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100038148, COSV50704665; called by muse, mutect2, varscan2
- NIPAL1 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99784520; called by muse, mutect2, varscan2
- NYAP1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.275); catalogued as rs1291253460, COSV55721719; called by muse, mutect2, varscan2
- OR10H2 | c.752T>C p.V251A | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV59946497; called by muse, mutect2, varscan2
- OR2B2 | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.39); catalogued as COSV100308205; called by muse, mutect2, varscan2
- OR2B2 | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100308207; called by muse, mutect2, varscan2
- OR4F15 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.192); catalogued as rs766043618, COSV59969453; called by muse, mutect2, varscan2
- OR5D18 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 18/115 reads (16%) | catalogued as COSV100450834, COSV61737173; called by muse, mutect2, varscan2
- OSBPL1A | c.2468G>A p.S823N (on ENST00000319481 / NM_080597.4; = p.S310N on NM_018030.4) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.346); catalogued as COSV100112479; called by muse, mutect2, varscan2
- OTOF | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99718637; called by muse, mutect2, varscan2
- PAIP1 | c.1319G>A p.G440E | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100166507; called by muse, mutect2
- PCDHA12 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as COSV56525069; called by muse, mutect2, varscan2
- PCDHA9 | c.1009C>T p.L337F | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.406); catalogued as COSV100969961; called by muse, mutect2, varscan2
- PGAM2 | c.342C>G p.I114M | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as COSV51977774, COSV99803851; called by muse, mutect2, varscan2
- PLCH1 | c.2756G>A p.R919Q (on ENST00000340059 / NM_001130960.2; = p.R911Q on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs759502342, COSV100397968; called by muse, mutect2, varscan2
- PNPT1 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99570376; called by muse, mutect2, varscan2
- PPP3CA | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100547942; called by muse, mutect2
- PRTG | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs764418980, COSV66837366; called by muse, mutect2, varscan2
- PTGER2 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as COSV99817663; called by muse, mutect2, varscan2
- PTGER4 | c.1451C>T p.S484L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); catalogued as COSV100201715; called by muse, mutect2, varscan2
- PTPRF | c.3881C>G p.S1294C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV100741128; called by muse, mutect2, varscan2
- PTPRM | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.056); catalogued as COSV100159507; called by muse, mutect2, varscan2
- RSPH3 | c.434C>T p.S145L (on ENST00000252655; = p.S3L on NM_031924.8) | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99396505; called by muse, mutect2, varscan2
- SERPINB9 | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV101046711; called by muse, mutect2, varscan2
- SFSWAP | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as rs944444737, COSV99906317; called by muse, mutect2, varscan2
- SFTPA2 | c.669G>C p.Q223H | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV100958828; called by muse, mutect2
- SLC12A2 | c.2794C>T p.Q932* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | catalogued as COSV52468989; called by muse, mutect2, varscan2
- SLC25A33 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100235861; called by muse, varscan2
- SLC2A12 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99260422; called by muse, mutect2, varscan2
- SLITRK6 | c.905C>G p.S302C | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as rs1329562642, COSV101233277; called by muse, mutect2, varscan2
- SOGA1 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs775021491, COSV99414847; called by muse, mutect2
- SUPT16H | c.2740G>C p.E914Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV99251630; called by muse, mutect2, varscan2
- SYT4 | c.294G>T p.K98N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99674241; called by muse, mutect2, varscan2
- TGFBR2 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55445679, COSV55458087, COSV55461455; called by muse, mutect2
- TMEM167A | c.143G>A p.R48K | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as COSV101491872, COSV71816101; called by muse, mutect2
- TMEM200C | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV101274859; called by muse, mutect2, varscan2
- TNPO2 | c.2433C>G p.I811M (on ENST00000425528 / NM_001382240.1; = p.I801M on NM_013433.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV100790401; called by muse, mutect2
- TRIM33 | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV100635650; called by muse, mutect2
- TTC14 | c.1954G>C p.E652Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.941); catalogued as COSV56012569; called by muse, mutect2, varscan2
- UBR2 | c.1146G>C p.L382F | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100867500; called by muse, mutect2
- USH1C | c.998A>G p.E333G | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV99141311; called by muse, mutect2, varscan2
- USH2A | c.14045G>C p.R4682T | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV56403661; called by muse, mutect2, varscan2
- USP38 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754958117, COSV100189425, COSV61026603; called by muse, mutect2, varscan2
- VIPR2 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100057955; called by muse, mutect2
- VLDLR | c.958G>C p.G320R | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV101173239; called by muse, mutect2, varscan2
- VPS4A | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs773370042, COSV99652096; called by muse, mutect2
- VPS4A | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99652101; called by muse, mutect2
- WFS1 | c.2190G>C p.W730C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766073085, COSV99901523; called by muse, mutect2, varscan2
- ZC3HAV1 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 12/196 reads (6%) | catalogued as COSV99648474; called by muse, mutect2
- ZNF518B | c.602G>A p.R201K | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100456827, COSV58724997; called by muse, mutect2
- ELAVL1 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- FBXW7 | c.1185dup p.S396* (on ENST00000281708 / NM_001349798.2; = p.S316* on NM_018315.5) | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, varscan2
- KIR3DL2 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 40/293 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TDRD3 | c.335G>A p.R112K | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.376); called by muse, mutect2
- ATP8A2 | c.3249G>A p.L1083= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV99683614; called by muse, mutect2, varscan2
- BTBD8 | c.534C>T p.F178= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV100730160; called by muse, mutect2, varscan2
- CDH10 | c.297T>C p.G99= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100052694; called by muse, mutect2
- CDK11B | c.1771C>T p.L591= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100478117; called by muse, mutect2, varscan2
- DNAH9 | c.7380G>T p.V2460= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as COSV99307462; called by muse, mutect2, varscan2
- FAM111A | c.855G>A p.E285= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs1164687171, COSV100659429; called by muse, mutect2, varscan2
- GRWD1 | c.696C>T p.T232= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs770126608, COSV53521067; called by muse, mutect2, varscan2
- HARBI1 | c.498G>A p.V166= | Silent (SNP) | VAF 32/195 reads (16%) | catalogued as COSV100365802, COSV56320778; called by muse, mutect2, varscan2
- IGDCC4 | c.210G>A p.V70= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as rs1567092930, COSV100733096; called by muse, mutect2
- IQSEC2 | c.2394C>T p.L798= (on ENST00000642864 / NM_001111125.3; = p.L593= on NM_015075.2) | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs782614364, COSV100945056, COSV64724039; called by muse, varscan2
- LINS1 | c.1389G>C p.L463= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV100130439; called by muse, mutect2, varscan2
- LIPE | c.1296G>T p.L432= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as COSV99734348; called by muse, mutect2
- MON2 | c.2796T>C p.V932= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV99743283; called by muse, mutect2, varscan2
- MYLK | c.2484C>T p.C828= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs748128807, COSV100659477; called by muse, mutect2, varscan2
- OR13C8 | c.27G>C p.S9= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV100623007; called by muse, mutect2, varscan2
- OR51D1 | c.678C>T p.F226= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV62913862; called by muse, mutect2, varscan2
- PCDH15 | c.867G>A p.L289= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100225812; called by muse, mutect2, varscan2
- PCDHA4 | c.2046G>A p.A682= | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as COSV63540205; called by muse, mutect2, varscan2
- PDE2A | c.1209C>G p.L403= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100558295; called by muse, mutect2
- PSMC3IP | c.525G>A p.K175= (on ENST00000393795 / NM_016556.4; = p.K163= on NM_013290.6) | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as rs925884381, COSV99518786, COSV99519045; called by muse, mutect2, varscan2
- SECISBP2 | c.558G>A p.E186= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV60528466; called by muse, mutect2
- SNW1 | c.687C>T p.V229= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99834496; called by muse, mutect2, varscan2
- SPEN | c.2154G>A p.E718= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs991568606, COSV101005511; called by muse, mutect2, varscan2
- ST18 | c.1875C>T p.D625= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV99390454; called by muse, mutect2, varscan2
- TAP1 | c.2323C>T p.L775= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV62754725; called by muse, mutect2, varscan2
- TTC14 | c.2253G>A p.L751= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1223828481, COSV99870273; called by mutect2, varscan2
- WDTC1 | c.798G>A p.L266= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs935330392, COSV100089382; called by muse, mutect2, varscan2
- ADGRA1 | chr10:133084848 G>C | 5'Flank (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100811036; called by muse, mutect2, varscan2
- CALCR | c.51+2961G>T | Intron (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100810788, COSV64011458; called by muse, mutect2, varscan2
- DLG2 | c.205-65604C>T | Intron (SNP) | VAF 14/68 reads (21%) | catalogued as COSV54632792; called by muse, mutect2, varscan2
- NGRN | c.*2T>G | 3'UTR (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100517988; called by muse, mutect2, varscan2
- RFX7 | c.-38C>G | 5'UTR (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100429206; called by muse, mutect2, varscan2
- RUFY3 | chr4:70794854 G>A | 3'Flank (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99887751; called by muse, mutect2
